Somatic mutation profile of tumor specimen MMRF_1720_1_BM_CD138pos (aliquot MMRF_1720_1_BM_CD138pos_T1_KBS5U_L04823) from MMRF case MMRF_1720, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.5 years (30,515 days).
Specimen MMRF_1720_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc6e2fb6-c089-49d4-b32c-b6040e57db22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1720_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1720_1_PB_Whole_C3_KBS5U_L04835; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a6e8ddb-cc4b-4b71-8818-44d98da771b2

The open-access MAF lists 164 somatic variants for this specimen: 61 protein-altering or splice-affecting, 17 silent, 86 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 56, Missense Mutation 50, Silent 17, Intron 14, 5'Flank 5, 5'UTR 5, Frame Shift Ins 4, 3'Flank 4, Nonsense Mutation 4, Frame Shift Del 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.698); catalogued as rs782659882; ClinVar: uncertain significance; called by muse, mutect2
- ADARB1 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs765006153; called by muse, mutect2, varscan2
- ADH1A | c.1029G>T p.L343F | Missense Mutation (SNP) | VAF 136/278 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV52925465; called by muse, mutect2, varscan2
- CAPS2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV60828441; called by muse, mutect2, varscan2
- DIS3 | c.2000T>A p.M667K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706189; called by muse, mutect2, varscan2
- DNAH5 | c.13738C>T p.R4580W | Missense Mutation (SNP) | VAF 100/161 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs771318876, COSV99455882; called by muse, mutect2, varscan2
- EGF | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764312466, COSV54480294; called by muse, mutect2, varscan2
- FAM47C | c.3055A>G p.M1019V | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs1291661515; called by muse, mutect2, varscan2
- FAM83B | c.1661A>C p.K554T | Missense Mutation (SNP) | VAF 125/248 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs1260987570; called by muse, mutect2, varscan2
- H1-4 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56800687; called by muse, mutect2, varscan2
- H4C8 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 286/602 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs1183618111; called by muse, mutect2, varscan2
- HOMEZ | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.548); catalogued as rs368363259; called by muse, mutect2, varscan2
- IL18RAP | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 110/220 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.07); catalogued as rs762379321, COSV51829417; called by muse, mutect2, varscan2
- INTS5 | c.3023C>T p.A1008V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.348); catalogued as rs1436299619; called by muse, mutect2, varscan2
- IZUMO1R | c.449G>A p.W150* (on ENST00000440961; = p.W157* on NM_001199206.3) | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as rs1565420231; called by muse, mutect2, varscan2
- LCORL | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 104/224 reads (46%) | catalogued as COSV58832186; called by muse, mutect2, varscan2
- PTPN14 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs547427299, COSV65287235; called by muse, mutect2, varscan2
- RYR1 | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs150442096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGSM1 | c.2884C>T p.R962C (on ENST00000400359 / NM_001039948.4; = p.R901C on NM_133454.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63082641; called by muse, mutect2
- SLC17A8 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 77/128 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1474758888; called by muse, mutect2, varscan2
- TGFB1 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs200868154, COSV54684009; called by muse, mutect2, varscan2
- TIGD6 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as rs745523369, COSV57060805; called by muse, mutect2, varscan2
- TRIM49C | c.1078A>G p.M360V | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1275934394; called by muse, mutect2, varscan2
- TXNDC2 | c.421G>T p.A141S (on ENST00000306084 / NM_001098529.2; = p.A74S on NM_032243.6) | Missense Mutation (SNP) | VAF 176/383 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.044); catalogued as rs1040633161; called by mutect2, varscan2
- ZBTB46 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs201899346; called by muse, mutect2, varscan2
- ZNF382 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 49/340 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs1249156925, COSV53089952; called by muse, mutect2, varscan2
- ABCA4 | c.5752G>T p.D1918Y | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ADNP | c.185C>A p.S62* | Nonsense Mutation (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- ARHGEF17 | c.2276T>C p.L759P | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ATMIN | c.2348A>T p.N783I | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.277); called by muse, mutect2
- BPIFA1 | c.39del p.L14* | Frame Shift Del (DEL) | VAF 32/366 reads (9%) | called by mutect2, pindel
- CFAP65 | c.3724C>T p.P1242S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYB5D1 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH8 | c.7150C>G p.P2384A | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPPK1 | c.5474A>C p.E1825A | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- FNDC3B | c.2949dup p.K984Qfs*6 | Frame Shift Ins (INS) | VAF 41/99 reads (41%) | called by mutect2, pindel, varscan2
- GFI1 | c.353del p.P118Lfs*80 | Frame Shift Del (DEL) | VAF 41/56 reads (73%) | called by mutect2, pindel, varscan2
- H4C8 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 288/601 reads (48%) | SIFT tolerated (0.07); called by muse, mutect2, varscan2
- HAUS6 | c.947A>T p.K316M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- HECTD4 | c.13210_13212del p.R4404del | In Frame Del (DEL) | VAF 35/116 reads (30%) | called by mutect2, pindel, varscan2
- INAVA | c.485dup p.A163Gfs*16 | Frame Shift Ins (INS) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- KIF2B | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MDGA2 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- NRXN2 | c.4889G>A p.R1630Q | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- PAN3 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 38/117 reads (32%) | called by muse, mutect2, varscan2
- POLR2A | c.2339A>C p.N780T | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- RASAL1 | c.2254A>G p.T752A | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMS3 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 125/265 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- SCLT1 | c.2027G>A p.R676K | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); called by muse, mutect2
- SEMG2 | c.1427G>C p.R476T | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2
- SEPTIN5 | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- SNX22 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTBN5 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); called by muse, mutect2
- TDP1 | c.1373dup p.S459Lfs*5 | Frame Shift Ins (INS) | VAF 37/101 reads (37%) | called by mutect2, pindel, varscan2
- THSD7A | c.3503T>C p.I1168T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMX3 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC13B | c.3208C>G p.L1070V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VAV2 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- WDR47 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF473 | c.1635dup p.V546Cfs*18 | Frame Shift Ins (INS) | VAF 50/251 reads (20%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.3168C>T p.A1056= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- ADAMTSL4 | c.1005G>A p.P335= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs759155216; called by muse, mutect2, varscan2
- ADRB1 | c.216C>T p.I72= | Silent (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- ASB17 | c.123C>T p.H41= | Silent (SNP) | VAF 102/207 reads (49%) | catalogued as rs574736873; called by muse, mutect2, varscan2
- C7orf33 | c.42C>T p.P14= | Silent (SNP) | VAF 25/131 reads (19%) | called by muse, mutect2, varscan2
- CES5A | c.225G>A p.P75= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs997115166, COSV51864856; called by muse, mutect2, varscan2
- FAM110A | c.837G>A p.K279= | Silent (SNP) | VAF 113/222 reads (51%) | catalogued as rs762302254; called by muse, mutect2, varscan2
- GGT5 | c.1749C>T p.A583= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs372251413; called by muse, mutect2, varscan2
- HTR1B | c.555C>T p.F185= | Silent (SNP) | VAF 91/170 reads (54%) | called by muse, mutect2, varscan2
- IGLV4-3 | c.150C>T p.Y50= | Silent (SNP) | VAF 71/74 reads (96%) | catalogued as rs1260414622; called by muse, mutect2, varscan2
- IRS2 | c.2373C>T p.G791= | Silent (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- KLHL40 | c.751C>T p.L251= | Silent (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- KRT27 | c.429C>T p.D143= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs376681073; called by muse, mutect2, varscan2
- MTHFD2 | c.12T>G p.T4= | Silent (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
- PARP10 | c.2322C>T p.F774= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs1308613430; called by muse, mutect2, varscan2
- PPIP5K1 | c.3411C>T p.S1137= (on ENST00000396923; = p.S1112= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- USP3 | c.477A>T p.T159= | Silent (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- AATK | c.*557A>G | 3'UTR (SNP) | VAF 53/220 reads (24%) | catalogued as rs1316159757; called by muse, mutect2, varscan2
- ACBD3 | c.904-123T>G | Intron (SNP) | VAF 2/12 reads (17%) | called by muse, mutect2
- AP3B2 | c.2440+140G>C | Intron (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- ARL11 | c.*2601A>G | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- ATM | c.*1040G>A | 3'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- BATF2 | c.*930G>T | 3'UTR (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021479 C>T | 5'Flank (SNP) | VAF 34/87 reads (39%) | catalogued as rs563689113, COSV55848997, COSV55852452; called by muse, mutect2, varscan2
- BICC1 | c.*2251G>A | 3'UTR (SNP) | VAF 49/235 reads (21%) | called by muse, mutect2, varscan2
- BMP6 | c.*1092_*1122del | 3'UTR (DEL) | VAF 37/95 reads (39%) | called by mutect2, pindel, varscan2
- C15orf54 | n.231G>A | RNA (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- C17orf80 | c.*1072C>T | 3'UTR (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- C1orf226 | c.*1591C>A | 3'UTR (SNP) | VAF 101/213 reads (47%) | called by muse, mutect2, varscan2
- CADM2 | chr3:86067674 A>C | 3'Flank (SNP) | VAF 61/121 reads (50%) | called by muse, mutect2, varscan2
- CALHM5 | c.*4584C>T | 3'UTR (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- CD55 | chr1:207321664 G>A | 5'Flank (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- CDK18 | c.*277G>A | 3'UTR (SNP) | VAF 30/181 reads (17%) | catalogued as rs1003583003; called by muse, mutect2, varscan2
- CHRM3 | c.*5284A>G | 3'UTR (SNP) | VAF 49/159 reads (31%) | catalogued as rs909529723; called by muse, mutect2, varscan2
- CLDN16 | c.-119A>G | 5'UTR (SNP) | VAF 74/166 reads (45%) | called by muse, mutect2, varscan2
- CSF3R | c.1071+108A>G | Intron (SNP) | VAF 6/10 reads (60%) | catalogued as rs1557592581; called by muse, varscan2
- CYYR1 | c.*35G>A | 3'UTR (SNP) | VAF 198/316 reads (63%) | catalogued as rs199720360; called by muse, mutect2, varscan2
- DUSP13 | c.*639G>T | 3'UTR (SNP) | VAF 20/58 reads (34%) | catalogued as rs148458852; called by muse, varscan2
- EN1 | c.-145dup | 5'UTR (INS) | VAF 13/32 reads (41%) | called by mutect2, pindel
- EPDR1 | c.*45G>A | 3'UTR (SNP) | VAF 30/111 reads (27%) | catalogued as rs1368658478, COSV52259018; called by muse, mutect2, varscan2
- FGFR3 | c.*55C>T | 3'UTR (SNP) | VAF 11/94 reads (12%) | catalogued as rs370530264; called by muse, mutect2, varscan2
- FOXC2 | c.*29C>A | 3'UTR (SNP) | VAF 37/136 reads (27%) | catalogued as rs1440000263; called by muse, mutect2, varscan2
- FOXK1 | c.*1393G>A | 3'UTR (SNP) | VAF 70/130 reads (54%) | called by muse, mutect2, varscan2
- GNG4 | c.*993G>A | 3'UTR (SNP) | VAF 50/144 reads (35%) | catalogued as rs770545913; called by muse, mutect2, varscan2
- GRHL2 | c.*244C>T | 3'UTR (SNP) | VAF 48/122 reads (39%) | called by muse, mutect2, varscan2
- GTF3C3 | c.1390+154A>G | Intron (SNP) | VAF 71/231 reads (31%) | called by muse, mutect2, varscan2
- HAPLN3 | c.*67T>G | 3'UTR (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- HELLS | c.1326+1021T>C | Intron (SNP) | VAF 15/23 reads (65%) | called by muse, mutect2, varscan2
- HIP1 | c.*1182G>A | 3'UTR (SNP) | VAF 23/100 reads (23%) | catalogued as rs782534282; called by muse, mutect2, varscan2
- HOXA7 | chr7:27153039 C>T | 3'Flank (SNP) | VAF 11/54 reads (20%) | catalogued as rs1369450083; called by muse, mutect2, varscan2
- INPP5D | chr2:233060136 A>G | 5'Flank (SNP) | VAF 23/81 reads (28%) | catalogued as rs917089799; called by muse, mutect2, varscan2
- KATNIP | c.408+1327G>A | Intron (SNP) | VAF 7/41 reads (17%) | catalogued as rs182525309; called by mutect2, varscan2
- KCTD20 | c.*2007G>A | 3'UTR (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- KCTD20 | c.*2009T>C | 3'UTR (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- KDM7A | c.*4941G>A | 3'UTR (SNP) | VAF 61/130 reads (47%) | called by muse, mutect2, varscan2
- KRTAP12-3 | c.*44G>A | 3'UTR (SNP) | VAF 17/95 reads (18%) | catalogued as rs587775545, COSV100554184; called by muse, mutect2, varscan2
- LAMA1 | c.1563+24_1563+25insCGG | Intron (INS) | VAF 3/21 reads (14%) | called by pindel, varscan2*
- LINC02272 | n.156A>T | RNA (SNP) | VAF 54/202 reads (27%) | called by muse, mutect2, varscan2
- LOXL3 | c.-12-275C>T | Intron (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- LTB | c.162+136G>A | Intron (SNP) | VAF 31/57 reads (54%) | catalogued as rs541787102; called by muse, mutect2, varscan2
- MAGI3 | c.*1C>A | 3'UTR (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- MAML2 | c.-767A>G | 5'UTR (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- METTL7A | chr12:50924691 T>C | 5'Flank (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- MLF1 | c.48-3571G>T | Intron (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- MMP16 | c.*3643G>A | 3'UTR (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- MTERF2 | c.-29C>T | 5'UTR (SNP) | VAF 69/252 reads (27%) | catalogued as rs764738368, COSV99526662; called by muse, mutect2, varscan2
- NAPEPLD | c.*1887C>G | 3'UTR (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- ONECUT1 | c.1105+8170A>C | Intron (SNP) | VAF 26/721 reads (4%) | called by muse, mutect2
- OSBPL6 | c.*3626T>C | 3'UTR (SNP) | VAF 8/72 reads (11%) | catalogued as rs1280092153; called by muse, mutect2, varscan2
- POU4F2 | c.*984C>T | 3'UTR (SNP) | VAF 28/60 reads (47%) | catalogued as rs768739276; called by muse, mutect2, varscan2
- PPP1R16B | c.*2414C>T | 3'UTR (SNP) | VAF 32/94 reads (34%) | catalogued as rs1161352568; called by muse, mutect2, varscan2
- PSD3 | c.*6894C>T | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- PTPRN2 | c.*366C>T | 3'UTR (SNP) | VAF 42/96 reads (44%) | catalogued as rs1013183442; called by muse, mutect2, varscan2
- PUS7L | c.*996G>A | 3'UTR (SNP) | VAF 9/225 reads (4%) | called by muse, mutect2
- RABL3 | c.*1365G>A | 3'UTR (SNP) | VAF 24/108 reads (22%) | catalogued as rs1389822226; called by muse, mutect2, varscan2
- RGS14 | c.-71C>T | 5'UTR (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- RRP1 | c.*59G>A | 3'UTR (SNP) | VAF 6/28 reads (21%) | catalogued as rs901091942; called by muse, mutect2, varscan2
- SAMD4A | c.*3569G>C | 3'UTR (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- SGK1 | c.152+32G>A | Intron (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- SLC5A3 | c.*8210C>T | 3'UTR (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- SNORA26 | chr4:52713460 T>A | 3'Flank (SNP) | VAF 64/134 reads (48%) | called by muse, mutect2, varscan2
- SOX8 | c.*268G>A | 3'UTR (SNP) | VAF 10/38 reads (26%) | catalogued as rs548050588; called by muse, mutect2, varscan2
- SPATA6 | c.*331dup | 3'UTR (INS) | VAF 30/100 reads (30%) | catalogued as rs1018802817; called by mutect2, varscan2
- SPOCK3 | c.*75C>T | 3'UTR (SNP) | VAF 17/92 reads (18%) | catalogued as COSV100693936; called by muse, mutect2, varscan2
- SPRTN | chr1:231338217 C>T | 5'Flank (SNP) | VAF 67/154 reads (44%) | called by muse, mutect2, varscan2
- SWAP70 | c.*99G>A | 3'UTR (SNP) | VAF 64/137 reads (47%) | called by muse, mutect2, varscan2
- TCERG1L | c.*294G>A | 3'UTR (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- TEF | c.*3101T>G | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- TLCD4 | c.*989T>C | 3'UTR (SNP) | VAF 64/116 reads (55%) | called by muse, mutect2, varscan2
- TLE4 | c.*237T>G | 3'UTR (SNP) | VAF 58/229 reads (25%) | called by muse, mutect2, varscan2
- TMEM132C | c.*1320G>A | 3'UTR (SNP) | VAF 57/117 reads (49%) | catalogued as rs751950243, COSV59420487; called by muse, mutect2, varscan2
- TMEM245 | c.1532+27del | Intron (DEL) | VAF 82/431 reads (19%) | called by mutect2, pindel, varscan2
- TMEM45A | c.*174G>A | 3'UTR (SNP) | VAF 29/146 reads (20%) | called by muse, mutect2, varscan2
- UGT2B4 | c.*271C>A | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- UGT2B4 | c.*270T>A | 3'UTR (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- UPF2 | c.*608G>C | 3'UTR (SNP) | VAF 72/146 reads (49%) | called by muse, mutect2, varscan2
- USP24 | c.*642T>C | 3'UTR (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- USP25 | chr21:15879626 C>T | 3'Flank (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- YPEL4 | c.-185+636A>T | Intron (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.*2025T>C | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- ZFR | c.*643del | 3'UTR (DEL) | VAF 28/119 reads (24%) | called by mutect2, pindel, varscan2
- ZFYVE9 | c.*56A>C | 3'UTR (SNP) | VAF 20/350 reads (6%) | called by muse, mutect2
- ZRANB2 | c.*1268G>A | 3'UTR (SNP) | VAF 43/141 reads (30%) | called by muse, mutect2, varscan2
